Somatic mutation profile of tumor specimen TCGA-D1-A103-01A (aliquot TCGA-D1-A103-01A-11D-A10M-09) from TCGA case TCGA-D1-A103, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 87.2 years (31,841 days).
Specimen TCGA-D1-A103-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0d2648a-b313-4cac-9e48-23a4aeb9d3b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A103-10A (Blood Derived Normal), aliquot TCGA-D1-A103-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26b51394-bd5c-40e7-b1b2-28cc46d57284

The open-access MAF lists 8,319 somatic variants for this specimen: 6,196 protein-altering or splice-affecting, 1,992 silent, 131 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,431, Silent 1,992, Nonsense Mutation 477, Splice Site 142, Splice Region 57, Frame Shift Ins 54, Intron 53, RNA 39, Frame Shift Del 25, 3'UTR 17, 5'UTR 10, 3'Flank 7.

Variants (750 of 8,319; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4610C>T p.T1537M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs62642575, CM003385; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ALDH6A1 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as rs781767219, COSV63247342; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1085307962, CM051844, HD070023, COSV65964052; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 87/226 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51649761; called by muse, mutect2, varscan2
- C8B | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as rs140813121, CM952411, COSV64778579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200646556, CM051874, COSV58826190; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEP83 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs1207804224, COSV51574274; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.4414C>T p.R1472* (on ENST00000646647 / NM_001170629.2; = p.R1193* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as rs991738444, COSV63219638; ClinVar: pathogenic; called by muse, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYBA | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs179363892, CM004698, CM101775, COSV99879778; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- FBN1 | c.1838-1G>A p.X613_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as rs1555399840, CS042163, CS161882, COSV57319905; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, varscan2
- HPS3 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121908316, CM013270, COSV56052762; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- INF2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1566778651, CM113751; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LMBRD1 | c.1222C>T p.R408* (on ENST00000649011; = p.R386* on NM_018368.4) | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as rs1380343985, COSV65296997; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs779617676, CM144063, COSV52274821; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NDUFS8 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.984); catalogued as rs750075208, COSV55834813; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV55904673; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRX | c.2857C>T p.R953* | Nonsense Mutation (SNP) | VAF 48/132 reads (36%) | catalogued as rs104894714, CM011006; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 206/261 reads (79%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 60/79 reads (76%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- SCN1A | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as rs398123585, CM065453, COSV57667669; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN8A | c.5614C>T p.R1872W | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053228, CM147204, COSV61987040, COSV99050261; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPR | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as rs779204655, CM123176, COSV52297859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397514914, CM114748, COSV54779446; ClinVar: not provided / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV99257286; called by mutect2, varscan2
- A2ML1 | c.94A>C p.N32H | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV55298306; called by muse, mutect2, varscan2
- A2ML1 | c.2689C>A p.L897I | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV55297525, COSV55298322; called by muse, mutect2, varscan2
- AAAS | c.771del p.R258Gfs*33 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs1184877278, CD067140; called by mutect2, pindel, varscan2
- AADACL4 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV66107189; called by muse, mutect2, varscan2
- AADAT | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV61788121; called by muse, varscan2
- AAMDC | c.58A>G p.N20D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV59021137; called by muse, mutect2, varscan2
- AASDHPPT | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53790465; called by muse, mutect2, varscan2
- AASDHPPT | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53788482, COSV99593144; called by muse, mutect2, varscan2
- AATF | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs139574552; called by muse, mutect2, varscan2
- ABCA1 | c.6372C>A p.C2124* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV66070387; called by muse, mutect2, varscan2
- ABCA1 | c.3883G>T p.D1295Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV66070389; called by muse, mutect2, varscan2
- ABCA12 | c.2923G>A p.V975I (on ENST00000272895 / NM_173076.3; = p.V657I on NM_015657.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1195598824, COSV55974901; called by muse, mutect2, varscan2
- ABCA12 | c.2381G>A p.G794E (on ENST00000272895 / NM_173076.3; = p.G476E on NM_015657.3) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55974915; called by muse, varscan2
- ABCA12 | c.2377G>A p.A793T (on ENST00000272895 / NM_173076.3; = p.A475T on NM_015657.3) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.05); catalogued as rs762700120, COSV55960289, COSV55974929; called by muse, varscan2
- ABCA12 | c.1838A>C p.K613T (on ENST00000272895 / NM_173076.3; = p.K295T on NM_015657.3) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as COSV55974944; called by muse, mutect2, varscan2
- ABCA13 | c.5161C>T p.H1721Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.73); catalogued as rs1051762849, COSV70043795; called by muse, mutect2, varscan2
- ABCA13 | c.11457G>T p.E3819D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV71294046; called by muse, mutect2, varscan2
- ABCA2 | c.4535T>C p.I1512T (on ENST00000614293; = p.I1482T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV55806582; called by muse, mutect2, varscan2
- ABCA4 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs778392569, COSV64670688, COSV64677865; called by muse, mutect2, varscan2
- ABCA5 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV67019018; called by muse, mutect2, varscan2
- ABCA7 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99566455; called by muse, mutect2
- ABCA8 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV52211686; called by muse, mutect2, varscan2
- ABCA8 | c.463A>G p.T155A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV52211710; called by muse, mutect2, varscan2
- ABCB1 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963199; called by muse, mutect2, varscan2
- ABCB11 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs766744091, COSV55585662; ClinVar: uncertain significance; called by muse, mutect2
- ABCB4 | c.2262C>A p.F754L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.242); catalogued as COSV55941520; called by muse, mutect2, varscan2
- ABCB5 | c.2122G>T p.V708L (on ENST00000404938 / NM_001163941.2; = p.V263L on NM_178559.6) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV51720398; called by muse, mutect2, varscan2
- ABCB7 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs771799598, COSV53723494; called by muse, mutect2, varscan2
- ABCB8 | c.901G>A p.A301T (on ENST00000297504 / NM_001282291.2; = p.A284T on NM_007188.5) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs747474835, COSV52510170; called by muse, mutect2, varscan2
- ABCB9 | c.1705C>T p.P569S (on ENST00000280560 / NM_019625.4; = p.P526S on NM_019624.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as COSV54894185; called by muse, mutect2, varscan2
- ABCC1 | c.2509G>A p.V837I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs754975789, COSV100578120; called by muse, mutect2
- ABCC10 | c.2083T>C p.Y695H (on ENST00000372530 / NM_001198934.2; = p.Y667H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55093805; called by muse, mutect2, varscan2
- ABCC10 | c.4245G>T p.K1415N (on ENST00000372530 / NM_001198934.2; = p.K1387N on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV55093816; called by muse, mutect2, varscan2
- ABCC11 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs781263618, COSV62322754; called by muse, mutect2, varscan2
- ABCC12 | c.2727G>T p.M909I | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV60912605, COSV60918149; called by muse, mutect2, varscan2
- ABCC12 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs569747930, COSV60918157; called by muse, varscan2
- ABCC3 | c.3983G>A p.G1328D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53328704; called by muse, mutect2, varscan2
- ABCC4 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as COSV65318149; called by muse, mutect2, varscan2
- ABCC5 | c.2015G>A p.S672N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55596210; called by muse, mutect2, varscan2
- ABCC6 | c.3937C>A p.L1313M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52747731; called by muse, mutect2, varscan2
- ABCC8 | c.4468T>C p.C1490R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56857529; called by muse, mutect2, varscan2
- ABCC8 | c.4029G>T p.K1343N | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV56857544; called by muse, mutect2, varscan2
- ABCC8 | c.1415C>A p.P472H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56857549; called by muse, mutect2, varscan2
- ABCD1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV99497842; called by muse, varscan2
- ABCD1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs541171928, COSV54387773; ClinVar: uncertain significance; called by muse, varscan2
- ABCD1 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs782760033, CP015755, COSV54387784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as CM107817, COSV54387796; called by muse, mutect2, varscan2
- ABCD2 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58049521, COSV58055009, COSV58055073; called by muse, varscan2
- ABCD2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 37/86 reads (43%) | catalogued as COSV58055082; called by muse, mutect2, varscan2
- ABCE1 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV56849014; called by muse, mutect2, varscan2
- ABCG2 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52949364; called by muse, mutect2, varscan2
- ABCG8 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs761344788, COSV99575366; called by muse, mutect2
- ABHD11 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56106515; called by muse, mutect2, varscan2
- ABHD12 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs746808749, COSV59288911; called by muse, mutect2, varscan2
- ABHD13 | c.558A>C p.K186N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV65535464; called by muse, mutect2, varscan2
- ABHD2 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61776098; called by muse, mutect2, varscan2
- ABHD4 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as COSV53530657; called by muse, mutect2, varscan2
- ABI3BP | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as rs1275957964, COSV52550944; called by muse, varscan2
- ABI3BP | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs553697655, COSV52528518; called by muse, mutect2, varscan2
- ABITRAM | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV59829825; called by muse, mutect2, varscan2
- ABLIM2 | c.1562A>C p.N521T (on ENST00000341937 / NM_001130084.2; = p.N555T on NM_001130083.2) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV56411505; called by muse, mutect2, varscan2
- ABRAXAS2 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 56/173 reads (32%) | catalogued as COSV53718441; called by muse, mutect2, varscan2
- ABTB1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51742871; called by muse, mutect2, varscan2
- AC005833.1 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs765535951, COSV52901649; called by muse, mutect2, varscan2
- AC008397.2 | c.1169G>A p.S390N | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV99442103; called by muse, mutect2
- AC013489.1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs373214566, COSV51549905; called by muse, mutect2, varscan2
- AC013489.1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.763); catalogued as COSV51553755; called by muse, mutect2, varscan2
- AC020907.6 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV59535020; called by muse, mutect2, varscan2
- AC068580.4 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.236); catalogued as rs868621027, COSV52590058; called by muse, mutect2, varscan2
- AC090517.4 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs201400339; called by muse, mutect2, varscan2
- AC098582.1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV52024542; called by muse, mutect2, varscan2
- AC109583.1 | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV58406560; called by muse, mutect2, varscan2
- AC131160.1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV57702289; called by muse, mutect2, varscan2
- AC134980.2 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV60909218; called by muse, mutect2, varscan2
- AC134980.2 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as rs200740894, COSV60907666; called by mutect2, varscan2
- ACAA2 | c.1109+1G>A p.X370_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as rs147811299; called by muse, mutect2, varscan2
- ACAA2 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53272290; called by muse, mutect2, varscan2
- ACACB | c.3983C>T p.P1328L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774198876, COSV58142582; called by muse, mutect2, varscan2
- ACAD10 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV58163009; called by muse, mutect2, varscan2
- ACAD11 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV53901393; called by muse, mutect2, varscan2
- ACADM | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63721069; called by muse, mutect2, varscan2
- ACADSB | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs763284518, COSV62551293, COSV62551463; called by muse, mutect2, varscan2
- ACAT1 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV99759363; called by muse, mutect2, varscan2
- ACCS | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs751260407, COSV55460246; called by muse, mutect2, varscan2
- ACE | c.2517G>T p.E839D | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV52012764; called by muse, mutect2, varscan2
- ACE2 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53027588, COSV99382555; called by muse, mutect2, varscan2
- ACKR4 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs746421374; called by muse, mutect2, varscan2
- ACLY | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV61252925; called by muse, mutect2, varscan2
- ACLY | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as rs781804168, COSV61252929; called by muse, mutect2, varscan2
- ACMSD | c.8T>G p.I3S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1378709017, COSV51609589; called by muse, varscan2
- ACMSD | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV51609611; called by muse, mutect2, varscan2
- ACMSD | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV51609619; called by muse, mutect2, varscan2
- ACOT12 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV56898012; called by muse, mutect2, varscan2
- ACOT8 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754407700, COSV54169727; called by muse, mutect2, varscan2
- ACOX2 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV57150784; called by muse, mutect2, varscan2
- ACP4 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV54518719; called by muse, mutect2, varscan2
- ACP4 | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54518727; called by muse, mutect2, varscan2
- ACSL5 | c.1315-1G>T p.X439_splice (on ENST00000354273; = p.X495_splice on NM_016234.3) | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV61133408; called by muse, mutect2, varscan2
- ACSM1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769122330, COSV54632818; called by muse, mutect2, varscan2
- ACTL8 | c.793T>C p.F265L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV64862654; called by muse, mutect2, varscan2
- ACTN1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV99518327; called by muse, mutect2
- ACTN4 | c.1843A>G p.T615A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV53150636; called by muse, mutect2, varscan2
- ACTR1A | c.1127T>G p.F376C | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53269320; called by muse, mutect2, varscan2
- ACTR2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53202628; called by muse, mutect2, varscan2
- ACTR3 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs760969306, COSV54302191; called by mutect2, varscan2
- ACTRT1 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100947485, COSV100947702; called by muse, varscan2
- ACTRT1 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as COSV64420030; called by muse, varscan2
- ACVR1B | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as COSV57780168; called by muse, mutect2, varscan2
- ACVR2A | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99604891, COSV99605241; called by muse, mutect2
- ACVR2B | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1321677268, COSV61701520, COSV61703135, COSV61703800; called by muse, mutect2, varscan2
- ADA2 | c.1494G>T p.K498N (on ENST00000262607; = p.K257N on NM_177405.3) | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52833793; called by muse, mutect2, varscan2
- ADAM11 | c.1781+2T>G p.X594_splice | Splice Site (SNP) | VAF 15/142 reads (11%) | catalogued as COSV99567729; called by muse, mutect2
- ADAM17 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60401818; called by muse, mutect2, varscan2
- ADAM19 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1157439299, COSV57438904; called by muse, mutect2, varscan2
- ADAM21 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs147193971; called by muse, mutect2, varscan2
- ADAM23 | c.514T>G p.L172V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52229577; called by muse, mutect2, varscan2
- ADAM7 | c.1348T>C p.S450P | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV51540548, COSV51546459; called by muse, varscan2
- ADAM7 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99443010, COSV99444672; called by muse, mutect2, varscan2
- ADAM8 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139328971; called by muse, mutect2, varscan2
- ADAMDEC1 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV56477526; called by muse, mutect2, varscan2
- ADAMTS10 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs782720992, COSV54359373; called by muse, mutect2, varscan2
- ADAMTS10 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs782300766, COSV54351658; called by muse, mutect2
- ADAMTS12 | c.2962C>T p.R988* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs373408673; called by mutect2, varscan2
- ADAMTS12 | c.2095T>G p.S699A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61278924; called by muse, mutect2, varscan2
- ADAMTS13 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV63023086; called by muse, mutect2, varscan2
- ADAMTS14 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs757762785, COSV64600965; called by muse, mutect2, varscan2
- ADAMTS16 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV57006548; called by muse, mutect2, varscan2
- ADAMTS16 | c.1208-1G>T p.X403_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV57006561; called by muse, mutect2, varscan2
- ADAMTS16 | c.2528T>C p.L843P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57006573; called by muse, mutect2, varscan2
- ADAMTS18 | c.1103T>C p.F368S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51422915; called by muse, mutect2, varscan2
- ADAMTS18 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as rs1318904239, COSV51422920; called by muse, mutect2, varscan2
- ADAMTS19 | c.2552T>C p.I851T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761566560, COSV50796592; called by muse, mutect2, varscan2
- ADAMTS2 | c.2140G>A p.V714M | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs574735794, COSV52368892; called by muse, mutect2, varscan2
- ADAMTS2 | c.1383-1G>T p.X461_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | catalogued as COSV51104044; called by muse, mutect2, varscan2
- ADAMTS20 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV67134539; called by muse, mutect2, varscan2
- ADAMTS20 | c.2351A>G p.K784R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as rs762547366, COSV67138904; called by muse, mutect2, varscan2
- ADAMTS4 | c.1760G>A p.C587Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63491148; called by muse, mutect2, varscan2
- ADAR | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186852211; called by muse, mutect2, varscan2
- ADARB2 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV67236782; called by muse, mutect2, varscan2
- ADAT1 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV57188412; called by muse, mutect2, varscan2
- ADCK5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370821655; called by muse, mutect2, varscan2
- ADCY1 | c.1010A>T p.E337V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV52038940, COSV52042189; called by muse, mutect2, varscan2
- ADCY1 | c.1549A>C p.M517L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV52042196; called by muse, mutect2, varscan2
- ADCY1 | c.2985G>T p.Q995H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52042207; called by muse, mutect2, varscan2
- ADCY10 | c.4647G>T p.E1549D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1332731500, COSV63244775; called by muse, mutect2, varscan2
- ADCY10 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as rs1460136079, COSV63244781; called by muse, mutect2, varscan2
- ADCY3 | c.835A>G p.M279V | Missense Mutation (SNP) | VAF 99/288 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV53172596; called by muse, mutect2, varscan2
- ADCY4 | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60257548; called by muse, mutect2, varscan2
- ADCY7 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs201627898, COSV54270739; called by muse, mutect2, varscan2
- ADCY7 | c.2460C>A p.Y820* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV54270745; called by muse, mutect2, varscan2
- ADCY9 | c.2260T>G p.F754V | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1010017999, COSV53581710; called by muse, mutect2, varscan2
- ADGRA1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV101658618; called by muse, mutect2, varscan2
- ADGRA1 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV63416837; called by muse, mutect2, varscan2
- ADGRB3 | c.1823G>T p.R608I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs747988050, COSV101000147, COSV65382174; called by muse, mutect2, varscan2
- ADGRB3 | c.1929+1G>A p.X643_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV65423797; called by muse, mutect2
- ADGRD1 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV55456864; called by muse, mutect2, varscan2
- ADGRE1 | c.2040C>A p.F680L | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51680851; called by muse, mutect2, varscan2
- ADGRF4 | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51957373; called by muse, mutect2, varscan2
- ADGRF4 | c.1932G>A p.Q644= | Splice Region (SNP) | VAF 7/15 reads (47%) | catalogued as rs1210019261, COSV51957386; called by muse, mutect2, varscan2
- ADGRF5 | c.3506C>A p.T1169N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51939936; called by muse, mutect2, varscan2
- ADGRG3 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV59652609; called by muse, mutect2, varscan2
- ADGRG4 | c.7585G>A p.A2529T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1300244606, COSV54966394; called by muse, mutect2, varscan2
- ADGRL1 | c.3158C>T p.A1053V (on ENST00000340736 / NM_001008701.3; = p.A1048V on NM_014921.5) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1568569440, COSV61564642; called by muse, mutect2
- ADGRL2 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54668469; called by muse, mutect2, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADH1C | c.687A>C p.K229N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72463653; called by muse, varscan2
- ADH4 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55502285; called by muse, mutect2, varscan2
- ADH4 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs748709323, COSV55502296; called by muse, mutect2, varscan2
- ADH7 | c.591A>C p.K197N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52923172; called by muse, mutect2, varscan2
- ADHFE1 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs1212148741, COSV52559088; called by muse, mutect2, varscan2
- ADHFE1 | c.1378T>C p.F460L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.325); catalogued as COSV52559107; called by muse, mutect2, varscan2
- ADNP | c.3047dup p.A1017Gfs*6 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV62426875; called by muse, mutect2, varscan2
- ADORA2A | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs200176420, COSV58380611; called by muse, mutect2, varscan2
- ADPGK | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV61175159; called by muse, mutect2, varscan2
- ADPRHL1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866656806, COSV62910910; called by muse, mutect2, varscan2
- ADRA1A | c.936T>G p.F312L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52373539; called by muse, mutect2, varscan2
- ADRA2B | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV69788301; called by muse, mutect2, varscan2
- ADRA2B | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1374379079, COSV69787249; called by muse, mutect2, varscan2
- ADSS2 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as COSV63694640, COSV63695668; called by muse, mutect2, varscan2
- AFDN | c.1875C>A p.S625R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV60056454; called by muse, varscan2
- AFDN | c.2999C>A p.P1000H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100653352; called by muse, mutect2
- AFF1 | c.2831C>A p.S944Y | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57123937; called by muse, mutect2, varscan2
- AFF1 | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs761540582, COSV57120313; called by muse, mutect2, varscan2
- AFF2 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 23/41 reads (56%) | catalogued as COSV54006985; called by muse, mutect2, varscan2
- AFG3L2 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777218796, COSV52313972, COSV52317336; called by muse, mutect2, varscan2
- AFG3L2 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52317344; called by muse, mutect2, varscan2
- AFM | c.318A>C p.Q106H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56922096; called by muse, mutect2, varscan2
- AFP | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV56927048; called by muse, mutect2, varscan2
- AFP | c.1061T>G p.F354C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56927064; called by muse, mutect2, varscan2
- AFP | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV56927078; called by muse, mutect2, varscan2
- AGA | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV52807653; called by muse, mutect2, varscan2
- AGAP1 | c.311-1G>T p.X104_splice | Splice Site (SNP) | VAF 98/260 reads (38%) | catalogued as COSV58338774; called by muse, mutect2, varscan2
- AGAP2 | c.2091G>T p.K697N (on ENST00000547588 / NM_001122772.2; = p.K361N on NM_014770.4) | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57731582; called by muse, mutect2, varscan2
- AGAP6 | c.676C>T p.R226C (on ENST00000374056 / NM_001365867.1; = p.R249C on NM_001077665.2) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs781828246, COSV65018387; called by muse, varscan2
- AGAP6 | c.749C>T p.A250V (on ENST00000374056 / NM_001365867.1; = p.A273V on NM_001077665.2) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs782128909, COSV65018392; called by muse, varscan2
- AGBL2 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54095324; called by muse, mutect2, varscan2
- AGBL4 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs771499735, COSV61893448; called by muse, mutect2, varscan2
- AGFG1 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59514722; called by muse, mutect2, varscan2
- AGGF1 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773138064, COSV57231214; called by muse, varscan2
- AGL | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV54058140; called by muse, mutect2, varscan2
- AGO2 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV55052602; called by muse, varscan2
- AGPAT2 | c.641A>T p.K214M | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV58248728; called by muse, mutect2, varscan2
- AGPAT3 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs762855528, COSV52368167; called by muse, mutect2, varscan2
- AGR2 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV68596585, COSV68597468; called by muse, mutect2, varscan2
- AGT | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs201569036, COSV64185526; called by muse, mutect2, varscan2
- AGTPBP1 | c.225+1G>A p.X75_splice | Splice Site (SNP) | VAF 41/118 reads (35%) | catalogued as COSV61277252; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2, varscan2
- AHCTF1 | c.6778G>A p.A2260T (on ENST00000366508; = p.A2234T on NM_015446.5) | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV58255177; called by muse, mutect2, varscan2
- AHCTF1 | c.6284C>A p.S2095* (on ENST00000366508; = p.S2069* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 75/192 reads (39%) | catalogued as COSV58255190; called by muse, mutect2, varscan2
- AHNAK | c.12142G>A p.D4048N | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57229738; called by muse, mutect2, varscan2
- AHNAK | c.5471C>T p.A1824V | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs780308369, COSV57229755; called by muse, mutect2, varscan2
- AHNAK2 | c.11427G>T p.K3809N | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs774454315, COSV60929880, COSV60930207; called by muse, mutect2, varscan2
- AHNAK2 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.164); catalogued as rs748111607, COSV60911337; called by muse, mutect2, varscan2
- AHR | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1246045330, COSV54126188; called by muse, mutect2, varscan2
- AICDA | c.544-2A>G p.X182_splice | Splice Site (SNP) | VAF 34/96 reads (35%) | catalogued as rs772388034, CS044746, COSV57565987; called by muse, varscan2
- AICDA | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs775814283, COSV57564503; called by muse, mutect2, varscan2
- AIFM1 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV54857694; called by muse, mutect2, varscan2
- AIFM3 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs771256400, COSV59004074; called by muse, mutect2, varscan2
- AIFM3 | c.511-2A>G p.X171_splice | Splice Site (SNP) | VAF 10/136 reads (7%) | catalogued as COSV100104961; called by muse, mutect2
- AIMP2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs368845750; called by muse, mutect2, varscan2
- AIRE | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as rs202018301, COSV52397051; called by muse, mutect2, varscan2
- AK7 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs750684821, COSV99967325; called by muse, mutect2, varscan2
- AKAP1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.631); catalogued as COSV58472922; called by muse, mutect2, varscan2
- AKAP11 | c.5134G>T p.D1712Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV99214232; called by muse, mutect2
- AKAP13 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV63469377; called by muse, mutect2, varscan2
- AKAP6 | c.4015C>A p.L1339I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV55214455, COSV55232693; called by muse, mutect2, varscan2
- AKAP8L | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.845); catalogued as rs747494504, COSV68474596; called by muse, mutect2, varscan2
- AKAP8L | c.33A>T p.E11D | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV68474604; called by muse, mutect2, varscan2
- AKAP9 | c.1816G>T p.E606* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100661747, COSV62357551; called by mutect2, varscan2
- AKAP9 | c.7003A>G p.T2335A (on ENST00000359028; = p.T2311A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.205); catalogued as rs142509451; called by muse, mutect2, varscan2
- AKAP9 | c.7283C>T p.T2428I (on ENST00000359028; = p.T2404I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs755642764, COSV62357574; called by muse, mutect2, varscan2
- AKAP9 | c.10322G>A p.R3441H (on ENST00000359028; = p.R3417H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs770556341, COSV62337987; called by muse, mutect2, varscan2
- AKNA | c.2440C>A p.L814I | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV56314939; called by muse, mutect2, varscan2
- AKR1B10 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV100610265, COSV62056569; called by muse, mutect2, varscan2
- AKR1B10 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV62056573; called by muse, mutect2, varscan2
- AKR1B10 | c.587T>G p.L196R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62056577; called by muse, mutect2, varscan2
- AKR1C4 | c.957T>A p.F319L | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs1457100500, COSV99578845; called by muse, mutect2
- AKR7A2 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV52516877; called by muse, mutect2, varscan2
- AKR7A3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs747280858, COSV64389738; called by muse, mutect2, varscan2
- AKTIP | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.217); catalogued as rs373752479; called by muse, mutect2, varscan2
- AL031777.2 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | catalogued as rs568525707, COSV61912392; called by muse, mutect2, varscan2
- AL121899.2 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs769115793, COSV67352315; called by muse, mutect2, varscan2
- AL121899.2 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV67352317; called by muse, mutect2, varscan2
- ALAD | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1564368258, COSV99474962; called by muse, mutect2, varscan2
- ALAS2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.547); catalogued as rs142713771, COSV58193238; called by muse, mutect2, varscan2
- ALCAM | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.233); catalogued as COSV60254786; called by muse, mutect2, varscan2
- ALCAM | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.519); catalogued as rs1217807803, COSV60254797; called by muse, mutect2, varscan2
- ALDH18A1 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV64663622; called by muse, mutect2, varscan2
- ALDH1L1 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs760592282, COSV56415093, COSV56419154; called by muse, mutect2, varscan2
- ALDH1L1 | c.2212A>G p.N738D | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56419165; called by muse, varscan2
- ALDH1L1 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs148110119, COSV56419174; called by muse, varscan2
- ALDH3A1 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.093); catalogued as COSV56736839; called by muse, mutect2, varscan2
- ALDH8A1 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.699); catalogued as COSV55644256; called by muse, mutect2, varscan2
- ALDOA | c.1237G>A p.V413I (on ENST00000642816 / NM_001243177.4; = p.V359I on NM_184041.5) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs373670009; called by muse, mutect2, varscan2
- ALDOB | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV66398611; called by muse, mutect2, varscan2
- ALDOC | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1441393520, COSV52024456; called by muse, mutect2, varscan2
- ALG10B | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs62001043, COSV100439962; called by muse, varscan2
- ALG10B | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58144878; called by muse, varscan2
- ALG8 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55203035; called by muse, mutect2, varscan2
- ALG9 | c.294A>C p.E98D | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV67645490; called by muse, mutect2, varscan2
- ALK | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV66588945; called by muse, varscan2
- ALKBH3 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs147054520; called by muse, varscan2
- ALOX15B | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV66480168; called by muse, mutect2, varscan2
- ALOX5AP | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66858411; called by muse, mutect2, varscan2
- ALOXE3 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV59073850, COSV59077922; called by muse, mutect2, varscan2
- ALOXE3 | c.353-1G>T p.X118_splice | Splice Site (SNP) | VAF 108/294 reads (37%) | catalogued as COSV59077937; called by muse, mutect2, varscan2
- ALPK2 | c.3541G>A p.E1181K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV64496981; called by muse, mutect2, varscan2
- ALPK2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs746498471, COSV64492089; called by muse, mutect2
- ALPK3 | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 40/117 reads (34%) | catalogued as rs1344615174, COSV51939552; called by muse, mutect2, varscan2
- ALS2 | c.4441C>A p.L1481M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51892368; called by muse, mutect2, varscan2
- ALS2 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs200109689; called by muse, mutect2, varscan2
- ALX3 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs1159900506, COSV63929107; called by muse, mutect2, varscan2
- AMER1 | c.1069A>G p.K357E | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57661661, COSV57667915, COSV57669983; called by muse, mutect2, varscan2
- AMER1 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 15/133 reads (11%) | catalogued as COSV57667930; called by muse, mutect2, varscan2
- AMFR | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as COSV51924253; called by muse, mutect2, varscan2
- AMFR | c.256-1G>T p.X86_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | catalogued as COSV51924260; called by muse, mutect2, varscan2
- AMIGO2 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.87); catalogued as COSV56975532; called by muse, mutect2, varscan2
- AMN | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54487754; called by muse, mutect2, varscan2
- AMOT | c.1927C>T p.R643C (on ENST00000371959 / NM_001113490.1; = p.R234C on NM_133265.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1414246520, COSV59068047; called by muse, mutect2, varscan2
- AMOTL1 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772911456, COSV58568894; called by mutect2, varscan2
- AMOTL2 | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51440860; called by muse, mutect2, varscan2
- AMPD1 | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62415397, COSV62415673; called by muse, mutect2, varscan2
- AMPD1 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.299); catalogued as COSV62418877; called by muse, mutect2, varscan2
- AMPD2 | c.456C>A p.D152E | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV56647179; called by muse, mutect2, varscan2
- AMPD2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756745194, COSV56649354; called by mutect2, varscan2
- AMPD3 | c.2271G>T p.M757I (on ENST00000396553 / NM_001025389.2; = p.M766I on NM_000480.3) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67329742, COSV67332349; called by muse, mutect2, varscan2
- AMY2B | c.1101C>T p.N367= | Splice Region (SNP) | VAF 36/83 reads (43%) | catalogued as rs148454896, COSV63717018; called by muse, varscan2
- AMZ1 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs999550677, COSV56689037; called by muse, mutect2, varscan2
- ANAPC1 | c.1171T>G p.S391A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV61979427; called by mutect2, varscan2
- ANAPC1 | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV61979430; called by muse, mutect2, varscan2
- ANAPC16 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV54965707; called by muse, mutect2, varscan2
- ANAPC7 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71444052; called by muse, mutect2, varscan2
- ANAPC7 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.029); catalogued as COSV71444053; called by muse, mutect2, varscan2
- ANGPT2 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57340266; called by muse, mutect2, varscan2
- ANGPT2 | c.1126A>C p.K376Q | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57340280; called by muse, mutect2, varscan2
- ANGPT4 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as COSV67922810; called by muse, mutect2, varscan2
- ANGPTL5 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs752245271, COSV57534568; called by muse, mutect2, varscan2
- ANGPTL6 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.655); catalogued as COSV53463853; called by muse, mutect2, varscan2
- ANGPTL7 | c.562T>C p.W188R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755991132, COSV63878035; called by muse, mutect2, varscan2
- ANK1 | c.5397G>T p.G1799= | Splice Region (SNP) | VAF 71/268 reads (26%) | catalogued as rs773545929, COSV55895336; called by muse, mutect2, varscan2
- ANK2 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52187809; called by muse, varscan2
- ANK2 | c.3038G>A p.R1013K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.396); catalogued as COSV52187826; called by muse, varscan2
- ANK3 | c.12877G>A p.V4293I (on ENST00000280772 / NM_001320874.2; = p.V917I on NM_001149.3) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.678); catalogued as rs772904316, COSV55080582; called by muse, mutect2, varscan2
- ANK3 | c.12110C>T p.S4037L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs370783050; called by muse, varscan2
- ANK3 | c.8085T>G p.I2695M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV55080630; called by muse, mutect2, varscan2
- ANK3 | c.6119A>G p.D2040G | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55080651; called by muse, mutect2, varscan2
- ANK3 | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55054175; called by muse, mutect2, varscan2
- ANKK1 | c.975C>A p.S325R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV58274193; called by muse, mutect2, varscan2
- ANKRD11 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56363394, COSV56371575; called by muse, mutect2, varscan2
- ANKRD12 | c.2360C>A p.S787Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.054); catalogued as COSV50847396; called by muse, mutect2, varscan2
- ANKRD12 | c.3764C>A p.S1255Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50847464; called by muse, mutect2, varscan2
- ANKRD12 | c.4430C>T p.S1477F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.347); catalogued as rs1349804524, COSV50847535; called by muse, mutect2, varscan2
- ANKRD13B | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1417508726, COSV67473627; called by muse, mutect2
- ANKRD13B | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100801405; called by muse, mutect2
- ANKRD17 | c.7277C>A p.P2426H | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100429771; called by muse, mutect2
- ANKRD17 | c.4654G>A p.A1552T | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV58227528; called by muse, mutect2, varscan2
- ANKRD17 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.613); catalogued as COSV58227538; called by muse, mutect2, varscan2
- ANKRD17 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV100429662, COSV58227546; called by muse, mutect2, varscan2
- ANKRD26 | c.3184C>A p.L1062I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763827709, COSV65778223; called by muse, varscan2
- ANKRD26 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV65778235; called by muse, varscan2
- ANKRD26 | c.2233C>A p.H745N | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV65778245; called by muse, mutect2, varscan2
- ANKRD27 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV60135914; called by muse, mutect2, varscan2
- ANKRD30A | c.2982G>T p.K994N (on ENST00000611781; = p.K938N on NM_052997.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64606049, COSV64610801; called by muse, mutect2, varscan2
- ANKRD30A | c.3910A>C p.N1304H (on ENST00000611781; = p.N1248H on NM_052997.2) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV64620822; called by muse, mutect2, varscan2
- ANKRD33 | c.95C>T p.T32M (on ENST00000340970 / NM_001304459.2; = p.T167M on NM_182608.4) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772815106, COSV56608417; called by muse, mutect2, varscan2
- ANKRD40 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV53328710; called by muse, mutect2, varscan2
- ANKRD42 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV52618314; called by mutect2, varscan2
- ANKRD44 | c.1211T>G p.F404C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as COSV56565759; called by muse, mutect2, varscan2
- ANKRD50 | c.3451C>T p.R1151C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs748502338, COSV72386290; called by muse, mutect2, varscan2
- ANKRD50 | c.2579G>T p.R860I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as COSV72386291; called by muse, mutect2, varscan2
- ANKS3 | c.1397A>T p.E466V | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58511672; called by muse, mutect2, varscan2
- ANKS4B | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV61140262; called by muse, mutect2, varscan2
- ANKS6 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62052144; called by muse, mutect2, varscan2
- ANLN | c.2883+1G>A p.X961_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV56079357; called by muse, mutect2, varscan2
- ANO10 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs1483548986, COSV52736192; called by muse, mutect2, varscan2
- ANO5 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.3); catalogued as COSV61090135; called by muse, mutect2, varscan2
- ANO9 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs940940079; called by muse, mutect2
- ANPEP | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as COSV100263398; called by muse, mutect2
- ANPEP | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as rs762703807, COSV55594841; called by muse, mutect2, varscan2
- ANXA7 | c.556G>A p.D186N (on ENST00000372919 / NM_001320880.2; = p.D164N on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.089); catalogued as rs142735473, COSV65824440; called by muse, mutect2, varscan2
- ANXA9 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.583); catalogued as COSV64485574; called by muse, mutect2, varscan2
- AOC2 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1172689768, COSV53828761; called by muse, mutect2, varscan2
- AOC3 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as rs201738850, COSV53826417; called by muse, mutect2, varscan2
- AOX1 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs765612875, COSV65983904; called by muse, mutect2, varscan2
- AP1M1 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV52229027; called by muse, mutect2, varscan2
- AP1M1 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.025); catalogued as rs200593906; called by muse, mutect2, varscan2
- AP1M1 | c.1050C>T p.G350= | Splice Region (SNP) | VAF 10/44 reads (23%) | catalogued as rs888741271, COSV52229050; called by muse, mutect2, varscan2
- AP1M1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs1414106796, COSV52229061; called by muse, mutect2, varscan2
- AP1S1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV61760910; called by muse, mutect2, varscan2
- AP1S1 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV50801981; called by muse, mutect2
- AP2M1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV53050193; called by muse, mutect2, varscan2
- AP3B1 | c.801A>C p.E267D | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV54892586; called by muse, varscan2
- AP3D1 | c.2100G>T p.E700D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as COSV61432858; called by muse, mutect2, varscan2
- AP3M2 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51530558; called by muse, mutect2, varscan2
- AP3M2 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1395502636, COSV51530575; called by muse, mutect2
- AP4B1 | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56724670, COSV56726953; called by muse, mutect2, varscan2
- AP4E1 | c.1367C>A p.S456* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV55918254, COSV55919997; called by muse, mutect2, varscan2
- AP4E1 | c.2842A>C p.N948H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55920008; called by muse, mutect2, varscan2
- APAF1 | c.1249G>A p.E417K (on ENST00000551964 / NM_181861.2; = p.E406K on NM_001160.3) | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV59668381; called by muse, varscan2
- APBA1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55237298; called by muse, mutect2, varscan2
- APBA2 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752622045, COSV101258138, COSV67104392; called by muse, mutect2, varscan2
- APBA3 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs868772901, COSV99516390; called by muse, mutect2
- APC | c.4576C>T p.P1526S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57380849; called by muse, mutect2, varscan2
- APC | c.5912C>A p.S1971Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754691867, CM044572, COSV57334200, COSV57362562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.6829T>G p.S2277A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV57380865; called by muse, mutect2, varscan2
- APC | c.8105C>T p.A2702V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV57380874; called by muse, mutect2, varscan2
- APLP1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs568306221, COSV55702927; called by muse, mutect2, varscan2
- APOB | c.11224T>G p.S3742A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.253); catalogued as COSV51951569; called by mutect2, varscan2
- APOB | c.9306C>A p.F3102L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.908); catalogued as COSV51922023; called by muse, mutect2, varscan2
- APOB | c.6537A>G p.I2179M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as COSV51951587; called by muse, mutect2, varscan2
- APOBEC3F | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV57911863; called by muse, varscan2
- APOBR | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.179); catalogued as COSV60493885; called by muse, mutect2, varscan2
- APOBR | c.1264C>A p.L422M (on ENST00000431282; = p.L431M on NM_018690.4) | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV60489362; called by muse, mutect2, varscan2
- APOBR | c.2162C>T p.A721V (on ENST00000431282; = p.A730V on NM_018690.4) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as rs111274264, COSV100112787; called by muse, mutect2, varscan2
- APOD | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV58402739; called by muse, mutect2, varscan2
- APP | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244541473, COSV60999774; called by muse, mutect2, varscan2
- APPBP2 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as COSV50029338; called by muse, mutect2, varscan2
- APPL1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.083); catalogued as COSV55703544; called by muse, mutect2, varscan2
- APPL1 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV55703557; called by muse, mutect2, varscan2
- ARAF | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51695257; called by muse, mutect2, varscan2
- ARAP1 | c.1430G>A p.G477D (on ENST00000393609 / NM_001040118.2; = p.G232D on NM_015242.4) | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV61994892; called by muse, mutect2, varscan2
- ARAP1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs760441635, COSV61994899; called by muse, mutect2, varscan2
- ARAP3 | c.2770G>T p.D924Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53354768; called by muse, mutect2, varscan2
- ARAP3 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1022286744, COSV53354780; called by muse, mutect2, varscan2
- ARC | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.952); catalogued as COSV63079770; called by muse, mutect2, varscan2
- ARF3 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.145); catalogued as COSV56741850; called by muse, mutect2, varscan2
- ARFGAP1 | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | catalogued as COSV100796714; called by muse, mutect2
- ARFGEF1 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV51616808; called by muse, mutect2, varscan2
- ARFRP1 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs750696744, COSV99423256; called by muse, mutect2, varscan2
- ARG1 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866970619, CM111039, COSV51580973, COSV99256050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARGFX | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as rs1330757949, COSV57683715; called by muse, mutect2, varscan2
- ARHGAP12 | c.998A>C p.D333A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV60966235; called by muse, varscan2
- ARHGAP12 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV60966243; called by muse, varscan2
- ARHGAP17 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1465006104, COSV51508771; called by muse, mutect2, varscan2
- ARHGAP17 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51512077; called by muse, mutect2, varscan2
- ARHGAP18 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100936424; called by muse, mutect2
- ARHGAP20 | c.3086C>A p.S1029Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV52811354, COSV52819056; called by muse, mutect2, varscan2
- ARHGAP20 | c.2785C>A p.L929I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52819080; called by muse, mutect2, varscan2
- ARHGAP20 | c.2414C>A p.S805Y | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.28); catalogued as COSV99504950; called by muse, mutect2, varscan2
- ARHGAP21 | c.3028C>T p.R1010* | Nonsense Mutation (SNP) | VAF 48/118 reads (41%) | catalogued as COSV57610891; called by muse, mutect2, varscan2
- ARHGAP22 | c.795C>T p.G265= | Splice Region (SNP) | VAF 77/215 reads (36%) | catalogued as COSV50984817; called by muse, mutect2, varscan2
- ARHGAP30 | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); catalogued as COSV63519251; called by muse, mutect2, varscan2
- ARHGAP30 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63519259; called by muse, varscan2
- ARHGAP31 | c.3908C>T p.A1303V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs376640443; called by muse, mutect2, varscan2
- ARHGAP35 | c.746A>C p.K249T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV68335535; called by muse, mutect2, varscan2
- ARHGAP4 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100509634; called by muse, mutect2
- ARHGAP4 | c.596G>T p.S199I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV63134562, COSV63134605; called by muse, mutect2, varscan2
- ARHGAP5 | c.2591G>A p.G864E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV100565631, COSV61536013; called by muse, mutect2, varscan2
- ARHGAP6 | c.1524A>G p.I508M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV57303171; called by muse, varscan2
- ARHGEF1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.575); catalogued as rs371771035; called by muse, mutect2, varscan2
- ARHGEF1 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs201550936, COSV61529596; called by muse, mutect2, varscan2
- ARHGEF10L | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63424916; called by muse, mutect2, varscan2
- ARHGEF11 | c.2927T>G p.I976S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV59358461; called by muse, mutect2, varscan2
- ARHGEF11 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs768597800, COSV63810625; called by muse, mutect2, varscan2
- ARHGEF12 | c.1204-1G>T p.X402_splice | Splice Site (SNP) | VAF 40/117 reads (34%) | catalogued as COSV63107265; called by muse, mutect2, varscan2
- ARHGEF12 | c.3097G>T p.D1033Y | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63107269; called by muse, mutect2, varscan2
- ARHGEF12 | c.3454G>A p.G1152R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.64); catalogued as COSV63104725; called by muse, mutect2, varscan2
- ARHGEF15 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62724801; called by muse, mutect2, varscan2
- ARHGEF17 | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV55237920; called by muse, mutect2, varscan2
- ARHGEF18 | c.3134G>A p.R1045H (on ENST00000359920 / NM_001130955.2; = p.R941H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs145300154; called by muse, mutect2, varscan2
- ARHGEF2 | c.776G>A p.R259H (on ENST00000361247 / NM_001162383.2; = p.R231H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs148865279; called by mutect2, varscan2
- ARHGEF28 | c.1395T>A p.F465L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55269745; called by muse, mutect2, varscan2
- ARHGEF3 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV56332408; called by muse, mutect2, varscan2
- ARHGEF38 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV54442202, COSV54445345; called by muse, mutect2, varscan2
- ARHGEF4 | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs752929676, COSV58130009; called by muse, mutect2, varscan2
- ARHGEF7 | c.2032A>G p.K678E (on ENST00000375741 / NM_001113511.2; = p.K500E on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV54551457; called by muse, mutect2, varscan2
- ARID2 | c.1567T>G p.F523V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57614284; called by muse, mutect2, varscan2
- ARID3B | c.716T>C p.I239T | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60559088; called by muse, mutect2, varscan2
- ARID4A | c.1938+1G>T p.X646_splice | Splice Site (SNP) | VAF 36/107 reads (34%) | catalogued as COSV62166579; called by muse, varscan2
- ARID4A | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.993); catalogued as rs371483660, COSV62163540; called by muse, mutect2, varscan2
- ARID4A | c.3083A>C p.E1028A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62166587; called by muse, mutect2, varscan2
- ARL15 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs200968142, COSV72288854; called by muse, mutect2, varscan2
- ARL6IP4 | c.1174A>G p.I392V (on ENST00000315580 / NM_018694.3; = p.I373V on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV54908601; called by muse, mutect2, varscan2
- ARMC3 | c.1741G>A p.G581S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs770918945, COSV53067523; called by muse, mutect2, varscan2
- ARMC3 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs150029689; called by muse, mutect2, varscan2
- ARMC3 | c.2169C>A p.F723L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53059310; called by muse, mutect2, varscan2
- ARMC8 | c.1745A>G p.N582S (on ENST00000469044 / NM_001363941.2; = p.N568S on NM_015396.6) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV58622558; called by muse, mutect2, varscan2
- ARMC9 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV63023618; called by muse, mutect2, varscan2
- ARMCX2 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV57531193; called by muse, mutect2, varscan2
- ARMCX5 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT tolerated (0.21); PolyPhen benign (0.353); catalogued as COSV55767552; called by muse, varscan2
- ARMCX5-GPRASP2 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV63439014; called by muse, mutect2, varscan2
- ARNT2 | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV57583016; called by muse, mutect2, varscan2
- ARR3 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs773226154, COSV57203779; called by muse, varscan2
- ARRDC1 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as rs201795480, COSV65060234, COSV65060321; called by muse, mutect2, varscan2
- ARRDC4 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99164439; called by muse, mutect2
- ARSA | c.981C>T p.G327= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as rs761449556, COSV53351270; called by muse, mutect2
- ARSB | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.181); catalogued as rs760875018, COSV53729104; called by muse, mutect2, varscan2
- ARSG | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs202165247; called by muse, mutect2, varscan2
- ARSL | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs756191732, COSV66964952, COSV66965711, COSV66965923; called by muse, mutect2, varscan2
- ARSL | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV66965926; called by muse, mutect2, varscan2
- ASAH2 | c.1625+1G>A p.X542_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as rs1230411007; called by muse, mutect2, varscan2
- ASAP1 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.084); catalogued as COSV63054305; called by muse, mutect2, varscan2
- ASB10 | c.451G>A p.A151T (on ENST00000420175 / NM_001142459.2; = p.A136T on NM_080871.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs370599172; called by muse, mutect2, varscan2
- ASB15 | c.1619T>C p.L540S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1207216790, COSV51929068; called by muse, varscan2
- ASB3 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs889327244, COSV55080018; called by muse, mutect2, varscan2
- ASB4 | c.56G>T p.R19I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV57507596, COSV99987137; called by muse, mutect2, varscan2
- ASB5 | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV56674307; called by muse, mutect2, varscan2
- ASB7 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV60419210; called by muse, varscan2
- ASB8 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs978834302, COSV56659032; called by muse, mutect2, varscan2
- ASCC3 | c.2773C>T p.R925W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371587845; called by muse, mutect2, varscan2
- ASCC3 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100226163; called by muse, mutect2, varscan2
- ASCL4 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.784); catalogued as rs377379976, COSV60817327; called by muse, mutect2, varscan2
- ASH1L | c.8227C>T p.R2743W (on ENST00000368346 / NM_001366177.2; = p.R2738W on NM_018489.3) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64213590; called by muse, mutect2, varscan2
- ASH1L | c.3645G>T p.E1215D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1332354740, COSV100853420, COSV64212648; called by muse, mutect2, varscan2
- ASH2L | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51701752; called by muse, mutect2, varscan2
- ASIC1 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV57320159; called by muse, mutect2, varscan2
- ASIC4 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV61733405; called by muse, mutect2, varscan2
- ASIC4 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559452870, COSV61733412; called by muse, mutect2, varscan2
- ASMTL | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 23/541 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.774); catalogued as COSV101187899; called by muse, mutect2
- ASMTL | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs774064974, COSV67243187; called by muse, mutect2, varscan2
- ASPG | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV71934140; called by muse, mutect2, varscan2
- ASPM | c.8133G>T p.K2711N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV99660900; called by mutect2, varscan2
- ASPM | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1557963670, COSV99660901; called by muse, mutect2
- ASS1 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 129/337 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV61690671; called by muse, mutect2, varscan2
- ASTE1 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as COSV53910458; called by muse, mutect2, varscan2
- ASTE1 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200808262, COSV53907523, COSV53908737; called by muse, mutect2, varscan2
- ASTN1 | c.3872G>T p.S1291I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV62506028; called by muse, mutect2, varscan2
- ASXL1 | c.1979G>A p.G660D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60121831; called by muse, mutect2, varscan2
- ASXL2 | c.4303C>T p.R1435W | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs561088610, COSV55467649; called by muse, mutect2, varscan2
- ASXL2 | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55454869, COSV55462123; called by muse, mutect2, varscan2
- ASXL2 | c.734T>C p.L245S | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55467704; called by muse, mutect2, varscan2
- ASZ1 | c.1348A>C p.I450L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52916355; called by muse, mutect2, varscan2
- ATAD2 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375014962, COSV54886467; called by muse, mutect2, varscan2
- ATCAY | c.360C>T p.D120= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as rs758678492, COSV56658098; called by muse, mutect2, varscan2
- ATCAY | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs762664911, COSV56658211; called by muse, mutect2, varscan2
- ATE1 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs765694044, COSV56443047; called by muse, mutect2, varscan2
- ATF2 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99908917; called by muse, mutect2, varscan2
- ATF6B | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV64352638; called by muse, mutect2, varscan2
- ATF7-NPFF | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as rs771626678, COSV57200660; called by muse, mutect2, varscan2
- ATF7IP | c.1835G>A p.C612Y | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.083); catalogued as COSV53777404; called by muse, mutect2, varscan2
- ATF7IP | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs770191292, COSV53770969; called by muse, mutect2, varscan2
- ATG10 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.409); catalogued as COSV56426740, COSV56432420; called by muse, mutect2, varscan2
- ATG16L2 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs553100451, COSV58362499; called by muse, mutect2, varscan2
- ATG4A | c.732C>A p.F244L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58967454; called by muse, mutect2, varscan2
- ATG4C | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV58608319; called by muse, mutect2, varscan2
- ATG4C | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1298805983, COSV58608329; called by muse, mutect2
- ATG9A | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs117094218, COSV60132091; called by muse, mutect2, varscan2
- ATL2 | c.1200G>T p.Q400H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV60056302; called by muse, mutect2
- ATL2 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV60056319; called by muse, varscan2
- ATOH8 | c.897C>A p.F299L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV60402021; called by muse, mutect2, varscan2
- ATP10A | c.3055C>T p.R1019W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201294665, COSV63514808; called by muse, mutect2, varscan2
- ATP10A | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.177); catalogued as COSV63523931; called by muse, mutect2, varscan2
- ATP10D | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202028690, COSV99906021; called by muse, mutect2
- ATP12A | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs769843394, COSV54517514, COSV54518970; called by muse, mutect2, varscan2
- ATP12A | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs770792516, COSV54523075; called by muse, varscan2
- ATP12A | c.2890C>A p.L964I | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV54523096; called by muse, mutect2, varscan2
- ATP13A3 | c.3662C>T p.A1221V (on ENST00000645319 / NM_001367549.1; = p.A1191V on NM_024524.3) | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs773710020, COSV55465165; called by muse, varscan2
- ATP13A3 | c.3434C>A p.T1145N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV55469451; called by muse, varscan2
- ATP13A3 | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55469461; called by muse, mutect2, varscan2
- ATP1A1 | c.2999T>C p.V1000A | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55194223; called by muse, mutect2, varscan2
- ATP1A2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as rs1335368737, COSV100768214, COSV63405793; called by muse, mutect2, varscan2
- ATP1A2 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63405797; called by muse, mutect2, varscan2
- ATP1A4 | c.2699A>G p.Y900C | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.726); catalogued as COSV63628473; called by muse, mutect2, varscan2
- ATP1B4 | c.670C>T p.R224C (on ENST00000218008 / NM_001142447.3; = p.R220C on NM_012069.5) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771260677, COSV54314349, COSV54314984; called by muse, mutect2, varscan2
- ATP2A2 | c.2097+1G>A p.X699_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as COSV57876321; called by muse, mutect2, varscan2
- ATP2A3 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs368619808; called by muse, mutect2, varscan2
- ATP2A3 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1021554812, COSV59226225; called by muse, mutect2, varscan2
- ATP2B4 | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58183646; called by muse, mutect2, varscan2
- ATP5MC1 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 56/535 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100582409; called by muse, mutect2, varscan2
- ATP5ME | c.137A>G p.E46G | Missense Mutation (SNP) | VAF 285/819 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV55330766; called by muse, mutect2, varscan2
- ATP5PB | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs768759849, COSV71953320; called by muse, mutect2, varscan2
- ATP6AP1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV63896270; called by muse, mutect2, varscan2
- ATP6AP2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs745734335, COSV65797833, COSV65798347; called by muse, varscan2
- ATP6AP2 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101011432, COSV65797478; called by muse, varscan2
- ATP6V0A2 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs188879714, COSV57752129; called by mutect2, varscan2
- ATP6V0A4 | c.2329G>A p.G777R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.888); catalogued as rs767611310, COSV59473584, COSV59479830; called by muse, mutect2, varscan2
- ATP6V0B | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV52545318; called by muse, mutect2, varscan2
- ATP6V0D1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52099853, COSV52100004; called by muse, mutect2, varscan2
- ATP6V0D2 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150345297; called by muse, mutect2, varscan2
- ATP6V0D2 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53417764; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV52352692; called by muse, varscan2
- ATP6V1B2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868258923, COSV52352759; called by muse, varscan2
- ATP6V1B2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs577956380, COSV99369247; called by muse, varscan2
- ATP6V1C1 | c.725G>T p.R242I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67778867; called by muse, mutect2, varscan2
- ATP6V1E2 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 41/95 reads (43%) | catalogued as COSV100120854, COSV60576633; called by muse, mutect2, varscan2
- ATP6V1G2 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV58215156; called by muse, mutect2, varscan2
- ATP7B | c.1286-1G>T p.X429_splice | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as COSV54443904, COSV99666031; called by muse, mutect2, varscan2
- ATP7B | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as rs1032122575, COSV54443913; called by muse, mutect2, varscan2
- ATP8A1 | c.3470C>T p.T1157M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs780548514, COSV52535378; called by muse, mutect2, varscan2
- ATP8B1 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.652); catalogued as rs112600442, COSV99377685; called by muse, mutect2, varscan2
- ATP8B2 | c.1726C>T p.R576W (on ENST00000672630; = p.R543W on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371680247; called by muse, mutect2, varscan2
- ATP8B3 | c.302G>T p.R101M | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV99402563; called by muse, mutect2
- ATP8B3 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV99402564; called by muse, mutect2, varscan2
- ATP9A | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs761097614, COSV100124509, COSV58762928; called by muse, mutect2, varscan2
- ATP9A | c.496-1G>T p.X166_splice | Splice Site (SNP) | VAF 62/198 reads (31%) | catalogued as COSV58771705; called by muse, mutect2, varscan2
- ATR | c.4934C>T p.S1645F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1216055957, COSV63392160; called by muse, mutect2, varscan2
- ATR | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs746970647, COSV63383507; called by muse, mutect2, varscan2
- ATRN | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772306017, COSV53534175; called by mutect2, varscan2
- ATRNL1 | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV61816686; called by muse, mutect2, varscan2
- ATRX | c.5375C>A p.S1792Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64883138; called by muse, mutect2, varscan2
- ATRX | c.4259A>C p.K1420T | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100971724, COSV64883144; called by muse, mutect2, varscan2
- ATRX | c.2874G>T p.Q958H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.188); catalogued as COSV64883148; called by muse, mutect2, varscan2
- ATRX | c.1095C>A p.N365K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as COSV64883155; called by muse, mutect2, varscan2
- ATRX | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV64870074; called by muse, mutect2, varscan2
- ATXN7L3 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV66989735; called by muse, mutect2, varscan2
- AUTS2 | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61429278; called by muse, mutect2, varscan2
- AUTS2 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs146659460, COSV100717316; called by muse, mutect2, varscan2
- AVIL | c.1870A>G p.K624E | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV57683756; called by muse, mutect2, varscan2
- AVL9 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV59469205; called by muse, mutect2, varscan2
- AWAT2 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV52144523; called by muse, mutect2, varscan2
- AXDND1 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62648165; called by muse, mutect2, varscan2
- AZGP1 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV52799370; called by muse, mutect2, varscan2
- AZIN1 | c.1055G>C p.S352T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV61481230; called by muse, mutect2, varscan2
- B3GAT1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV100437848, COSV57000628; called by muse, mutect2, varscan2
- B3GNT9 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs986472546, COSV54629401; called by muse, varscan2
- B4GALNT1 | c.1385-1G>T p.X462_splice | Splice Site (SNP) | VAF 32/78 reads (41%) | catalogued as COSV57544805; called by muse, mutect2, varscan2
- B4GALNT1 | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1322992281, COSV57544809; called by muse, mutect2, varscan2
- B4GALNT3 | c.2378C>A p.P793H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56757844; called by muse, mutect2, varscan2
- B4GALT2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs771308766, COSV52545323; called by muse, mutect2, varscan2
- B4GALT4 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs773571617, COSV63295762; called by muse, mutect2, varscan2
- B4GALT6 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV52705085; called by muse, mutect2, varscan2
- B4GALT6 | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV52705094; called by muse, mutect2, varscan2
- B4GAT1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60820702; called by muse, varscan2
- BACH2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57590039, COSV57592010; called by muse, mutect2, varscan2
- BAHCC1 | c.7582C>T p.R2528W | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57033064; called by muse, mutect2, varscan2
- BAIAP3 | c.882G>T p.W294C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100181462; called by muse, mutect2
- BANK1 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV59841855, COSV59849697; called by muse, mutect2, varscan2
- BAZ1B | c.2470A>C p.I824L | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59994537; called by muse, mutect2, varscan2
- BAZ2A | c.4242C>A p.F1414L | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV51640479; called by muse, mutect2, varscan2
- BAZ2B | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1426546428, COSV54276760, COSV99680995; called by muse, mutect2, varscan2
- BAZ2B | c.3594G>T p.K1198N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs753314578, COSV54276766; called by muse, mutect2, varscan2
- BAZ2B | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV54276779; called by muse, mutect2, varscan2
- BBOX1 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV54193858; called by muse, mutect2, varscan2
- BBS5 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV54754307; called by muse, mutect2, varscan2
- BBS7 | c.393T>A p.H131Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV52659407; called by muse, mutect2, varscan2
- BBX | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as rs201416014, COSV57894436; called by muse, mutect2, varscan2
- BCAM | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV54304785; called by muse, mutect2, varscan2
- BCAT1 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs751073733, COSV53917465; called by muse, mutect2, varscan2
- BCL11B | c.2522G>A p.R841H (on ENST00000357195 / NM_001282237.2; = p.R770H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61738715; called by muse, mutect2, varscan2
- BCL2L15 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761350107, COSV63643337; called by muse, mutect2, varscan2
- BCL9 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs782112724, COSV52349924; called by muse, mutect2, varscan2
- BCL9L | c.4072C>T p.H1358Y | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV52689076; called by muse, mutect2, varscan2
- BCLAF3 | c.1882G>T p.D628Y (on ENST00000379682 / NM_001367774.1; = p.D599Y on NM_198279.3) | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV61414984; called by muse, mutect2, varscan2
- BCLAF3 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV61414993; called by muse, mutect2, varscan2
- BCO1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV50733792; called by muse, mutect2, varscan2
- BCOR | c.3986A>G p.K1329R (on ENST00000378444 / NM_001123385.2; = p.K1295R on NM_017745.6) | Missense Mutation (SNP) | VAF 95/282 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV60718062; called by muse, mutect2, varscan2
- BCOR | c.1754G>T p.R585M | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60718077; called by muse, mutect2, varscan2
- BCOR | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs1243995590, COSV60718097; called by muse, varscan2
- BCORL1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs267606346, COSV54393478, COSV99498287; called by muse, mutect2, varscan2
- BCR | c.3470C>T p.P1157L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs1034990413, COSV59935673; called by muse, mutect2, varscan2
- BDH1 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64019841; called by muse, mutect2, varscan2
- BDP1 | c.1633T>C p.S545P | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV62434589; called by muse, mutect2, varscan2
- BDP1 | c.4174G>T p.E1392* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV62429799, COSV62434599; called by muse, mutect2, varscan2
- BDP1 | c.7349G>T p.R2450I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs544031248, COSV62428641; called by muse, mutect2, varscan2
- BEND4 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV72469017, COSV72469089; called by muse, mutect2
- BEND4 | c.1114C>A p.L372M | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV72469395; called by muse, mutect2, varscan2
- BEND7 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs201677598, COSV61991222; called by muse, mutect2, varscan2
- BEST2 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.771); catalogued as COSV50358847; called by muse, mutect2, varscan2
- BEX1 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.964); catalogued as COSV65580041, COSV65580664; called by muse, mutect2, varscan2
- BFSP1 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 62/151 reads (41%) | catalogued as COSV64901845; called by muse, mutect2, varscan2
- BHLHE41 | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 117/323 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54379675; called by muse, mutect2, varscan2
- BHMT2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs141648685, COSV54874678; called by muse, varscan2
- BICC1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65862331; called by muse, mutect2, varscan2
- BIRC3 | c.1330T>G p.L444V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV54819919; called by muse, mutect2, varscan2
- BIRC6 | c.8521G>T p.E2841* | Nonsense Mutation (SNP) | VAF 38/86 reads (44%) | catalogued as COSV70205598; called by muse, mutect2, varscan2
- BIRC6 | c.8815G>A p.E2939K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV70205608; called by muse, mutect2, varscan2
- BIRC6 | c.12718G>T p.E4240* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV70205626; called by muse, mutect2, varscan2
- BIRC6 | c.13745C>A p.A4582D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70205635; called by muse, mutect2, varscan2
- BIRC6 | c.14195G>A p.R4732Q | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs772472693, COSV70205647; called by muse, mutect2, varscan2
- BLK | c.1009C>A p.L337M | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV52056108; called by muse, mutect2, varscan2
- BLOC1S5 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV55241687; called by muse, mutect2, varscan2
- BMP1 | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60483737; called by muse, mutect2, varscan2
- BMP1 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs752066503, COSV60479579; called by muse, mutect2, varscan2
- BMP2K | c.988-1G>T p.X330_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as rs1329692280, COSV58593160; called by muse, mutect2, varscan2
- BMP3 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV51094875; called by muse, mutect2, varscan2
- BMP4 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1268997444, COSV55416241; called by muse, mutect2, varscan2
- BMP7 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1292292967, COSV67782581; called by muse, mutect2, varscan2
- BMP7 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV67779508; called by muse, mutect2, varscan2
- BMPER | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV51831022; called by muse, mutect2, varscan2
- BMPER | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs532833810, COSV51828583; called by muse, mutect2, varscan2
- BMPR1A | c.531-1G>T p.X177_splice | Splice Site (SNP) | VAF 23/57 reads (40%) | catalogued as COSV64408590; called by muse, mutect2, varscan2
- BMPR1B | c.1204A>G p.S402G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52781732; called by muse, mutect2, varscan2
- BMS1 | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65735436; called by muse, mutect2, varscan2
- BMS1 | c.1814A>G p.E605G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65735440; called by muse, mutect2, varscan2
- BNIPL | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV54848917; called by muse, mutect2, varscan2
- BOD1L1 | c.8698G>T p.V2900F | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.483); catalogued as COSV99240083; called by muse, mutect2
- BOD1L1 | c.8185C>A p.H2729N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV50061809; called by muse, varscan2
- BOD1L1 | c.7824T>G p.D2608E | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.107); catalogued as COSV50062010; called by muse, mutect2, varscan2
- BOD1L1 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772980975, COSV50062216; called by muse, mutect2, varscan2
- BOLA3 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 140/386 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54877478; called by muse, varscan2
- BOLL | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs761048419, COSV56577389, COSV99987033; called by muse, mutect2, varscan2
- BPI | c.593G>A p.R198Q (on ENST00000262865; = p.R194Q on NM_001725.3) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs749629986, COSV53404895, COSV53408318; called by muse, mutect2, varscan2
- BPIFC | c.452T>G p.F151C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.552); catalogued as COSV55915743; called by muse, varscan2
- BPTF | c.5815G>A p.E1939K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs780605303, COSV58845552; called by muse, mutect2, varscan2
- BPTF | c.6424A>G p.T2142A | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58846388; called by muse, mutect2, varscan2
- BRD1 | c.1913G>A p.C638Y | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53458839; called by muse, mutect2, varscan2
- BRD1 | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53461413; called by muse, mutect2, varscan2
- BRD1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53458624, COSV53461430; called by muse, mutect2, varscan2
- BRD1 | c.1281G>T p.R427S | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV53461453, COSV99349513; called by muse, mutect2, varscan2
- BRD1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99350149; called by muse, mutect2
- BRD4 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141552564, COSV54594750; called by muse, mutect2, varscan2
- BRD4 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs759001252, COSV54594780; called by muse, mutect2, varscan2
- BRD9 | c.402C>T p.A134= | Splice Region (SNP) | VAF 101/282 reads (36%) | catalogued as rs758667843, COSV51319209, COSV51319691; called by muse, mutect2, varscan2
- BRDT | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV62867507; called by muse, mutect2, varscan2
- BRF1 | c.983T>G p.I328S | Missense Mutation (SNP) | VAF 120/335 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59273531; called by muse, mutect2, varscan2
- BRF1 | c.438G>A p.P146= | Splice Region (SNP) | VAF 27/53 reads (51%) | catalogued as rs1219364193, COSV59273548; called by muse, mutect2, varscan2
- BRINP2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as rs780568954, COSV64175922; called by muse, mutect2, varscan2
- BRINP3 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100819509, COSV66540863; called by muse, varscan2
- BRIP1 | c.1860G>T p.M620I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); catalogued as COSV52008541; called by muse, mutect2, varscan2
- BRIP1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs375246789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF1 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 124/400 reads (31%) | catalogued as COSV57407972; called by muse, mutect2, varscan2
- BRWD1 | c.5525T>A p.M1842K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as COSV60902603; called by muse, mutect2, varscan2
- BRWD1 | c.5123C>T p.A1708V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV60902614; called by muse, mutect2, varscan2
- BRWD1 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV60903539; called by muse, varscan2
- BRWD3 | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV64748316, COSV64753533; called by muse, mutect2, varscan2
- BRWD3 | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64753540; called by muse, mutect2, varscan2
- BSN | c.269G>T p.R90I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV56527067; called by muse, mutect2, varscan2
- BSN | c.10805C>T p.A3602V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV56516828; called by muse, mutect2, varscan2
- BST2 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV53089787; called by muse, mutect2, varscan2
- BST2 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.912); catalogued as rs764053823, COSV53089801; called by muse, mutect2, varscan2
- BTBD16 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV53266893; called by muse, mutect2, varscan2
- BTBD7 | c.2990C>T p.T997M | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.05); catalogued as rs374545941; called by muse, mutect2
- BTBD7 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54138907; called by muse, mutect2, varscan2
- BTBD8 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61547060, COSV61547720; called by muse, mutect2, varscan2
- BTF3 | c.557A>G p.D186G (on ENST00000380591 / NM_001037637.1; = p.D142G on NM_001207.4) | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as rs991534070, COSV59964718; called by muse, mutect2, varscan2
- BTG4 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV63636932; called by muse, mutect2, varscan2
- BTNL8 | c.319T>A p.L107M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV51461769; called by muse, mutect2, varscan2
- BUD31 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV52867640; called by muse, mutect2, varscan2
- C10orf71 | c.1866G>T p.E622D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV60512916; called by muse, mutect2, varscan2
- C12orf40 | c.1293T>G p.N431K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV61137607; called by muse, varscan2
- C12orf50 | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100072436; called by muse, mutect2
- C12orf57 | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV57547516; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as COSV62298237; called by mutect2, varscan2
- C16orf54 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as rs1171068332, COSV61477260; called by muse, mutect2, varscan2
- C16orf71 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as rs150534835, COSV54794502; called by muse, mutect2, varscan2
- C16orf72 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1366213938, COSV59916594; called by muse, mutect2, varscan2
- C16orf78 | c.393T>C p.S131= | Splice Region (SNP) | VAF 10/24 reads (42%) | catalogued as COSV54558367; called by muse, mutect2, varscan2
- C16orf90 | c.545G>T p.R182I (on ENST00000399645 / NM_001353385.2; = p.R173I on NM_001080524.2) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV68714634; called by muse, mutect2, varscan2
- C18orf21 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV52449975; called by muse, mutect2, varscan2
- C19orf18 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58708004; called by muse, varscan2
- C19orf44 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54172071; called by muse, mutect2, varscan2
- C1QA | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV65890080; called by muse, mutect2, varscan2
- C1QTNF1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV59264315; called by muse, mutect2, varscan2
- C1QTNF2 | c.985G>A p.E329K (on ENST00000393975; = p.E284K on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.853); catalogued as rs768627769, COSV67433300; called by muse, mutect2, varscan2
- C1R | c.767T>G p.I256S (on ENST00000536053 / NM_001354346.2; = p.I242S on NM_001733.7) | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73293796, COSV73293834; called by muse, mutect2, varscan2
- C1RL | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.31); catalogued as rs1024784263, COSV56926687; called by muse, mutect2, varscan2
- C1orf116 | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV63944721; called by muse, mutect2, varscan2
- C1orf127 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs771629101, COSV65436888; called by muse, mutect2, varscan2
- C1orf194 | c.172C>T p.R58W (on ENST00000369948 / NM_001245025.3; = p.R46W on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs369546573, COSV64049943; called by muse, mutect2, varscan2
- C1orf198 | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64176591; called by muse, mutect2, varscan2
- C1orf35 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs140393278; called by muse, mutect2, varscan2
- C1orf50 | c.356T>G p.I119S | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV65308470; called by muse, mutect2, varscan2
- C1orf52 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99641071; called by muse, mutect2
- C20orf194 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52702614; called by muse, mutect2, varscan2
- C22orf31 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV99326487; called by muse, mutect2
- C2orf16 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.546); catalogued as COSV68647045; called by muse, mutect2, varscan2
- C2orf16 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62678226; called by muse, mutect2, varscan2
- C2orf50 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV67510926; called by muse, mutect2, varscan2
- C2orf66 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs970928747, COSV61099177; called by muse, mutect2, varscan2
- C2orf78 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV68519363, COSV68519462; called by muse, mutect2, varscan2
- C2orf80 | c.545G>T p.R182M | Missense Mutation (SNP) | VAF 15/360 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.208); catalogued as COSV100378569; called by muse, mutect2
- C3orf14 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV51707610; called by muse, mutect2, varscan2
- C3orf20 | c.1577G>T p.R526I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV53787324; called by muse, mutect2, varscan2
- C3orf70 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.834); catalogued as COSV58590537; called by muse, mutect2, varscan2
- C5orf22 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745442454, COSV57599943; called by muse, mutect2, varscan2
- C6 | c.2522G>A p.R841H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.35); catalogued as rs763860114, COSV54707949; called by muse, mutect2, varscan2
- C6 | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs1167933473, COSV54709747; called by muse, mutect2, varscan2
- C6orf201 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100326691, COSV60986012; called by muse, mutect2, varscan2
- C7 | c.2065G>A p.V689I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV57480660; called by muse, mutect2, varscan2
- C7 | c.2207G>T p.R736M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV57480667; called by muse, mutect2, varscan2
7,569 further variants in this file (5,446 protein-altering or splice-affecting, 1,992 silent, 131 other) are not listed here.
